Surgical pathology report (de-identified scan), TCGA case TCGA-C4-A0F6, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Indivumed, specimen TCGA-C4-A0F6-01A (Primary Tumor).

ICD-0-3

Carcinoma, urothelial, NOS 8120/3

Site: bladder, NOS C67.9

1/28/11 lw

Diagnosis

Poorly differentiated solid urothelial carcinoma of the bladder with infiltration of the bladder wall and infiltration of the perivesical fatty tissue (pT3a, G3). Carcinomatous lymphangitis, Tumor-free preparation margins in the region of the bladder, ureter and vagina, Tumor-free uterus with atrophic endometrium. Epithelium of ectocervix shows no dysplasia. Tumor-free ovaries with bilateral corpus albicans. Tumor-free tubes on both sides.

Tumor classification (in light of the previous frozen section analysis):
pT3b, L1, pN0 (0/10), G3, R0

Source: NCI Genomic Data Commons file dbedee65-e5e8-4176-8ea8-46d640f85c1e (TCGA-C4-A0F6.6141ED7C-45EC-4157-9064-47EA7C945CE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).